Somatic mutation profile of tumor specimen TCGA-UB-A7MC-01A (aliquot TCGA-UB-A7MC-01A-11D-A33Q-10) from TCGA case TCGA-UB-A7MC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 59.5 years (21,733 days).
Specimen TCGA-UB-A7MC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47303b82-d371-454f-9eec-af98fd6738eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UB-A7MC-10A (Blood Derived Normal), aliquot TCGA-UB-A7MC-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baf4c906-6b79-4220-86cf-23c416fd6c74

The open-access MAF lists 75 somatic variants for this specimen: 61 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 13, Frame Shift Del 5, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 47/110 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 42/45 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACOX2 | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs75760511, COSV57149941; called by muse, mutect2, varscan2
- ANK1 | c.2767G>C p.G923R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55872764, COSV55887544; called by muse, mutect2, varscan2
- ANKRD11 | c.2621C>T p.A874V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.038); catalogued as COSV56365798; called by muse, mutect2, varscan2
- ARID5B | c.2062T>C p.S688P | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54425299; called by muse, mutect2
- ATAD2 | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54883779; called by muse, mutect2, varscan2
- ATP10B | c.2235G>T p.Q745H | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV59158473; called by muse, mutect2, varscan2
- BRPF3 | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 5/151 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs1282535130, COSV100325625; called by muse, mutect2
- BSN | c.4450T>C p.S1484P | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99607531; called by muse, mutect2
- CDH4 | c.238G>T p.G80W | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV64664190; called by muse, mutect2, varscan2
- CELSR2 | c.1649A>G p.D550G | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV54775930; called by muse, mutect2, varscan2
- CEP83 | c.1972A>T p.M658L | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51579088; called by muse, mutect2, varscan2
- COL3A1 | c.3209C>A p.A1070D | Missense Mutation (SNP) | VAF 91/171 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as COSV100482682, COSV58593081; called by muse, mutect2, varscan2
- DNM2 | c.1134G>T p.E378D | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as COSV58967014, COSV58968648; called by muse, mutect2, varscan2
- IGSF10 | c.5251C>T p.R1751C | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs369808974, COSV56788442; called by muse, mutect2, varscan2
- IL6 | c.179T>A p.I60N | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51733418, COSV51733669; called by muse, mutect2, varscan2
- KANSL1 | c.3086A>G p.Q1029R (on ENST00000574590 / NM_001193465.2; = p.Q1030R on NM_015443.4) | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.946); catalogued as COSV52243569; called by muse, mutect2, varscan2
- LCE1F | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 108/646 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV57669657; called by muse, mutect2, varscan2
- LTK | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs55683312, COSV53028509; called by muse, mutect2, varscan2
- NCOA3 | c.1940A>G p.K647R | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV59070854; called by muse, mutect2, varscan2
- NTRK1 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs866288494, COSV62323057; called by muse, mutect2
- NUP88 | c.1996C>A p.Q666K | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT tolerated (0.2); PolyPhen benign (0.138); catalogued as COSV52586578; called by muse, mutect2, varscan2
- OBSCN | c.11918C>T p.T3973I | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs767373154, COSV52799048; called by muse, mutect2, varscan2
- OR4M1 | c.774C>A p.Y258* | Nonsense Mutation (SNP) | VAF 77/347 reads (22%) | catalogued as COSV60062572; called by muse, mutect2, varscan2
- OSR1 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV55345980; called by muse, mutect2, varscan2
- OTOP2 | c.1126G>C p.A376P | Missense Mutation (SNP) | VAF 63/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58881441, COSV58882739; called by muse, mutect2, varscan2
- OTX2 | c.866T>C p.L289S (on ENST00000408990 / NM_172337.3; = p.L297S on NM_021728.4) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100257805; called by muse, mutect2
- PCDHA1 | c.1960C>G p.H654D | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV65375612; called by muse, mutect2, varscan2
- PCDHB16 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as rs782583100, COSV53366442; called by muse, mutect2, varscan2
- PDRG1 | c.103A>G p.T35A | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1199326281, COSV52431908; called by muse, mutect2, varscan2
- PHF2 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs779187383, COSV63682353; called by muse, mutect2, varscan2
- PHF3 | c.2351C>G p.T784S | Missense Mutation (SNP) | VAF 101/207 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV50326666; called by muse, mutect2, varscan2
- PIPOX | c.575G>A p.S192N | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV60142724; called by muse, mutect2, varscan2
- POC5 | c.513G>A p.K171= (on ENST00000428202 / NM_001099271.2; = p.K146= on NM_152408.2) | Splice Region (SNP) | VAF 26/87 reads (30%) | catalogued as COSV66842684; called by muse, mutect2, varscan2
- PRAMEF4 | c.419G>C p.C140S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as rs1226511463, COSV52439833; called by muse, mutect2, varscan2
- RASA3 | c.2261A>C p.K754T | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0.131); catalogued as COSV61863807; called by muse, mutect2, varscan2
- SENP7 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV58614952; called by muse, mutect2, varscan2
- SFMBT2 | c.2627del p.K876Sfs*36 | Frame Shift Del (DEL) | VAF 33/76 reads (43%) | catalogued as COSV100739878; called by mutect2, pindel, varscan2
- SLC30A1 | c.1252C>A p.Q418K | Missense Mutation (SNP) | VAF 116/121 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65361362; called by muse, mutect2, varscan2
- SLCO1C1 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV56876057; called by muse, mutect2, varscan2
- SMUG1 | c.300A>C p.E100D | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV54540020; called by muse, mutect2, varscan2
- STAB2 | c.1451T>C p.V484A | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.334); catalogued as rs752616430, COSV66342742; called by muse, mutect2, varscan2
- STX2 | c.512G>C p.G171A | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55435047; called by muse, mutect2
- TAAR2 | c.394T>G p.F132V (on ENST00000367931 / NM_001033080.1; = p.F87V on NM_014626.3) | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51579534; called by muse, mutect2
- TM6SF1 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 8/245 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV99362507, COSV99362944; called by muse, mutect2
- WASHC3 | c.163C>G p.L55V | Missense Mutation (SNP) | VAF 104/186 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as COSV53532740; called by muse, mutect2, varscan2
- XIRP1 | c.4370C>A p.A1457D | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs775350289, COSV100453210, COSV61139770; called by muse, mutect2, varscan2
- XIRP2 | c.5768C>T p.S1923L (on ENST00000628543; = p.S2098L on NM_152381.6) | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV54698421; called by muse, mutect2, varscan2
- ZBTB8OS | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as COSV59386110; called by muse, mutect2, varscan2
- ZNF518B | c.2638C>G p.L880V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58723557; called by muse, mutect2, varscan2
- ZNF831 | c.4787A>G p.Y1596C | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs760005581, COSV64042741; called by muse, mutect2, varscan2
- ZSCAN21 | c.1205G>C p.G402A | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.499); catalogued as COSV52851566; called by muse, mutect2, varscan2
- ZSWIM1 | c.729C>A p.H243Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV54849482, COSV99667027; called by muse, mutect2, varscan2
- ARHGEF40 | c.2543C>T p.A848V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- ELOA2 | c.349A>T p.T117S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2
- HLA-DMB | c.274_280dup p.L94Qfs*35 | Frame Shift Ins (INS) | VAF 54/138 reads (39%) | called by mutect2, varscan2
- HSD3B7 | c.270del p.D91Tfs*22 | Frame Shift Del (DEL) | VAF 38/159 reads (24%) | called by mutect2, pindel, varscan2
- PRKDC | c.5111_5126del p.G1704Dfs*35 | Frame Shift Del (DEL) | VAF 39/174 reads (22%) | called by mutect2, pindel, varscan2
- SLC5A8 | c.1262del p.G421Vfs*26 | Frame Shift Del (DEL) | VAF 53/207 reads (26%) | called by mutect2, pindel, varscan2
- SLIT2 | c.737del p.N246Mfs*2 | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | called by mutect2, pindel, varscan2
- CSMD1 | c.3243C>T p.A1081= (on ENST00000520002; = p.A1080= on NM_033225.6) | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV59350890; called by muse, varscan2
- EMC7 | c.621G>A p.L207= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as COSV56628422; called by muse, mutect2, varscan2
- IQSEC2 | c.2535G>A p.R845= (on ENST00000642864 / NM_001111125.3; = p.R640= on NM_015075.2) | Silent (SNP) | VAF 77/84 reads (92%) | catalogued as COSV64726865; called by muse, mutect2, varscan2
- ISG20 | c.12C>T p.S4= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV60144134; called by muse, mutect2, varscan2
- MTCL1 | c.1854C>T p.S618= (on ENST00000306329 / NM_001378206.1; = p.S258= on NM_015210.4) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV60408735; called by muse, mutect2, varscan2
- MYO16 | c.2994G>A p.K998= | Silent (SNP) | VAF 288/496 reads (58%) | catalogued as COSV62755148, COSV62763442; called by mutect2, varscan2
- PCCA | c.937C>A p.R313= | Silent (SNP) | VAF 53/167 reads (32%) | catalogued as CM991019, COSV66195258; called by muse, mutect2, varscan2
- PLA2G4D | c.279T>C p.Y93= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs1354350876, COSV51822203; called by muse, mutect2, varscan2
- PRNP | c.423C>T p.F141= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs764920854, COSV65173547; called by muse, mutect2, varscan2
- SERBP1 | c.30C>A p.G10= | Silent (SNP) | VAF 46/124 reads (37%) | catalogued as COSV63413940; called by muse, mutect2, varscan2
- SLC29A2 | c.654T>C p.F218= | Silent (SNP) | VAF 48/54 reads (89%) | catalogued as COSV60803806; called by muse, mutect2, varscan2
- SPATA33 | c.195A>T p.A65= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV53683877; called by muse, mutect2, varscan2
- SULT1C3 | c.873G>A p.K291= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as COSV61252439; called by muse, varscan2
- MROH8 | c.370+2516G>A | Intron (SNP) | VAF 23/82 reads (28%) | catalogued as COSV54122168; called by muse, mutect2, varscan2
